Gene-level copy-number profile of tumor specimen RC-B6SL-TTP1-A from RC case RC-B6SL, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of multiple regions; Age at diagnosis: 52.4 years (19,144 days).
Specimen RC-B6SL-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9cc9204a-9ab4-4f9e-9caf-35c426318280.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SL-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/ff356490-0e3e-43e1-a328-23b931342324

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 141; copy number 1: 8,074; copy number 2: 43,672; copy number 3: 6,491; copy number 4: 241; copy number 5: 151; copy number 6: 29; copy number 7: 79; copy number 11: 4; copy number 13: 12; copy number 21: 3.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:135,531,455–135,725,270, 3 genes: R3HDM1, RNU6-512P, MIR128-1.
- chr3:20,388,249–20,390,562, 1 gene: AC116096.1.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr8:74,320,613–74,518,007, 3 genes (within-gene range 0–1): GDAP1, AC103952.1, Y_RNA.
- chr9:74,935,176–75,028,423, 6 genes: AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3.
- chr14:22,304,054–22,552,156, 73 genes (within-gene range 0–3) (broad region; genes not listed).
- chr16:72,112,157–72,176,878, 1 gene (within-gene range 0–2): PMFBP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 278 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,906,196–248,937,043, 3 genes, copy number 6: PGBD2, RNU6-1205P, RPL23AP25.
- chr10:1,159,768–1,737,525, 4 genes, copy number 6 (within-gene range 3–6): LINC00200, ADARB2, AL392083.2, AL392083.1.
- chr10:1,526,637–9,287,057, 132 genes, copy number 5–21 (broad region; genes not listed).
- chr14:106,683,395–106,879,812, 24 genes, copy number 5: SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr17:19,296,596–19,685,760, 30 genes, copy number 5 (within-gene range 3–5): EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2.
- chr18:80,147,924–80,247,514, 4 genes, copy number 5: PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:58,543,299–58,605,223, 11 genes, copy number 5: RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr20:46,060,991–49,278,426, 66 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr21:46,598,604–46,691,226, 4 genes, copy number 5: S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 5,303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
